Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6529, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6529-01A (Primary Tumor).

TCGA – D5 – 6529

page 1 / 1

Examination: Histopathological examination

Material: **Multiple organ resection – segment of the large intestine**

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis:

Examination performed on

Macroscopic description:

17 cm length of the large intestine with mesentery sized 16 x 6 x 3cm, a 7 cm segment of the small intestine, and a 6.7 cm appendix. Ulcerous tumour found in the mucosa, sized 4.7 x 4 x 1,2 cm. The lesion placed 7.0 cm from the proximal cut end, 12.0 cm from the distal cut end, and 0 cm from the Baughin valve. Minimum side margin is 5.0 cm.

Microscopic description:

Adenocarcinoma tubuloapillare (G1). Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae. Minimum side margin is 5 cm. Incision lines free of neoplastic lesions. Lymphonodulitis reactiva lymphonodorum (No XIX).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli (G1; Dukes B, Astler-Coller B2; pT3; pN0).

Tubulopapillary adenocarcinoma of the colon

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3a8770a0-2ec0-455e-acda-0a6c3ef800ef (TCGA-D5-6529.68504EB4-8724-494A-A886-B0C22BC0FB09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).